Somatic mutation profile of tumor specimen MP2PRT-PAVMXX-TMP1-A (aliquot MP2PRT-PAVMXX-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVMXX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (921 days).
Specimen MP2PRT-PAVMXX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c7d7594-370f-4861-88ed-2ffd162150df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMXX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMXX-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4f93ab-8774-4b15-b988-0633b035dea6

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 110/346 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 198/676 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- HEATR1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as rs759130190; called by muse, mutect2, varscan2
- KRT76 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760847107; called by muse, mutect2, varscan2
- PCDHA1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 196/574 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as COSV104430107; called by muse, varscan2
- UNC5C | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs762175329, COSV71659626; called by muse, varscan2
- DYSF | c.4049C>A p.A1350D | Missense Mutation (SNP) | VAF 120/281 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EPHA5 | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 19/674 reads (3%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.954); called by muse, mutect2
- EXOC6B | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRIM75P | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCDC182 | c.117C>T p.P39= | Silent (SNP) | VAF 113/361 reads (31%) | called by muse, mutect2, varscan2
- CPZ | c.318C>A p.A106= (on ENST00000360986 / NM_001014447.3; = p.A95= on NM_003652.3) | Silent (SNP) | VAF 185/768 reads (24%) | catalogued as COSV59921588; called by mutect2, varscan2
- DNAAF3 | c.453G>A p.L151= (on ENST00000524407 / NM_001256715.2; = p.L198= on NM_178837.4) | Silent (SNP) | VAF 168/427 reads (39%) | called by muse, mutect2, varscan2
- HIVEP2 | c.2295G>T p.L765= | Silent (SNP) | VAF 20/744 reads (3%) | called by muse, mutect2
- PLPPR4 | c.1254G>A p.P418= | Silent (SNP) | VAF 101/275 reads (37%) | catalogued as rs202142961, COSV64564643; called by muse, mutect2, varscan2
- RBMXL2 | c.459G>A p.P153= | Silent (SNP) | VAF 24/664 reads (4%) | catalogued as rs1205241998; called by muse, mutect2
